Somatic mutation profile of tumor specimen TCGA-4B-A93V-01A (aliquot TCGA-4B-A93V-01A-11D-A397-08) from TCGA case TCGA-4B-A93V, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 52.1 years (19,035 days).
Specimen TCGA-4B-A93V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e9593d3-994f-45ed-af55-577c1bfbf7c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4B-A93V-10A (Blood Derived Normal), aliquot TCGA-4B-A93V-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59339970-dcc3-4b6c-bce5-cb6448170c1b

The open-access MAF lists 148 somatic variants for this specimen: 117 protein-altering or splice-affecting, 30 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 101, Silent 30, Nonsense Mutation 7, Frame Shift Del 5, Splice Site 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 24/43 reads (56%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.641A>G p.H214R | Missense Mutation (SNP) | VAF 19/30 reads (63%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs1057519992, CM103210, COSV52670202, COSV52732998, COSV52834506, COSV52887765; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AADAC | c.369T>G p.S123R | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs145320004, COSV99233291; called by muse, mutect2, varscan2
- ADAM2 | c.40C>A p.L14M | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.114); catalogued as COSV99697473; called by muse, mutect2, varscan2
- ANK2 | c.8945T>C p.L2982S | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); catalogued as COSV100002085; called by muse, mutect2, varscan2
- ANKRD30A | c.2552G>T p.R851I (on ENST00000611781; = p.R795I on NM_052997.2) | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as rs1405837998, COSV100652884, COSV100653678; called by muse, mutect2, varscan2
- ANO2 | c.2215A>T p.T739S (on ENST00000356134 / NM_001278597.3; = p.T743S on NM_001278596.3) | Missense Mutation (SNP) | VAF 62/102 reads (61%) | SIFT tolerated (0.25); PolyPhen benign (0.053); catalogued as COSV100501244; called by muse, mutect2, varscan2
- ARHGAP6 | c.1300G>T p.V434F | Missense Mutation (SNP) | VAF 84/157 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100273006; called by muse, mutect2, varscan2
- ATG2A | c.937G>C p.A313P | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as COSV101034497; called by muse, mutect2, varscan2
- BPIFC | c.1217G>T p.R406I | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1217715977, COSV100301085, COSV55911246; called by muse, mutect2, varscan2
- BRCA1 | c.4112G>T p.G1371V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs1441376381, COSV100524344, COSV58797180; called by muse, mutect2, varscan2
- BRWD1 | c.2704G>A p.E902K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.122); catalogued as COSV100313553; called by muse, mutect2, varscan2
- BST1 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); catalogued as COSV99399992; called by muse, mutect2
- CD163L1 | c.2621G>T p.C874F | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100550176; called by muse, mutect2, varscan2
- CHST6 | c.280G>T p.D94Y | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100178451, COSV60000690; called by muse, mutect2, varscan2
- CLIP1 | c.1153G>T p.V385L | Missense Mutation (SNP) | VAF 43/74 reads (58%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.565); catalogued as rs759562298, COSV100211862, COSV56808848; called by muse, mutect2, varscan2
- CLSTN1 | c.523G>A p.E175K (on ENST00000377298 / NM_001009566.3; = p.E165K on NM_014944.4) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1382854238, COSV100790615; called by muse, mutect2, varscan2
- COL11A1 | c.4483G>T p.G1495C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100616965; called by muse, mutect2, varscan2
- COL5A1 | c.2767C>A p.P923T | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV100880050, COSV65667439; called by muse, mutect2, varscan2
- DGAT2 | c.577G>T p.A193S | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99929817; called by muse, mutect2, varscan2
- DPP10 | c.1624G>A p.D542N | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs202170246, COSV59695021; called by muse, mutect2, varscan2
- ECE1 | c.2251G>T p.E751* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as COSV99941960; called by muse, mutect2, varscan2
- EMCN | c.418A>G p.S140G | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as rs1213399113, COSV99598447; called by muse, mutect2, varscan2
- EML1 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.184); catalogued as rs1159799095, COSV51745322; called by muse, mutect2, varscan2
- EP400 | c.6103G>A p.D2035N | Missense Mutation (SNP) | VAF 106/161 reads (66%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.526); catalogued as COSV100201372; called by muse, mutect2, varscan2
- ERICH5 | c.419C>A p.A140D | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100582793; called by muse, mutect2, varscan2
- ETNPPL | c.182A>T p.H61L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99625302; called by muse, mutect2
- EYS | c.650G>T p.C217F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as rs1222379109, COSV100676624; called by muse, mutect2, varscan2
- F11 | c.907G>T p.G303* | Nonsense Mutation (SNP) | VAF 67/154 reads (44%) | catalogued as COSV99251590, COSV99251973; called by muse, mutect2, varscan2
- FLG | c.9350G>T p.S3117I | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV64241931; called by muse, mutect2, varscan2
- FLG | c.8378G>T p.S2793I | Missense Mutation (SNP) | VAF 118/474 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.675); catalogued as COSV100911651; called by muse, mutect2, varscan2
- FMO4 | c.1553G>T p.W518L | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746928621, COSV100882071; called by muse, mutect2, varscan2
- GABRG3 | c.151C>A p.L51I | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100407815, COSV61510781; called by muse, mutect2, varscan2
- GRIN2A | c.2596-1G>T p.X866_splice | Splice Site (SNP) | VAF 14/64 reads (22%) | catalogued as COSV100410127, COSV58045019; called by muse, mutect2, varscan2
- HCAR1 | c.901C>T p.Q301* | Nonsense Mutation (SNP) | VAF 121/182 reads (66%) | catalogued as rs1449002872, COSV100811641; called by muse, mutect2, varscan2
- HDAC4 | c.2993A>T p.D998V | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV100613670; called by muse, mutect2
- HERC2 | c.11962G>T p.V3988L | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV99874428; called by muse, mutect2, varscan2
- HRH2 | c.119G>C p.C40S | Missense Mutation (SNP) | VAF 75/127 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV51576562; called by muse, mutect2, varscan2
- HS3ST6 | c.817G>A p.V273I | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.104); catalogued as rs200947593; called by muse, mutect2
- HSF5 | c.1788G>T p.E596D | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.689); catalogued as COSV100090340; called by muse, mutect2, varscan2
- KCNU1 | c.1631G>A p.R544Q | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as rs185223273, COSV67754087; called by muse, mutect2
- KEAP1 | c.597G>T p.L199F | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99407887; called by muse, mutect2, varscan2
- KLK5 | c.207T>G p.N69K | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.32); PolyPhen benign (0.289); catalogued as COSV100307081; called by muse, mutect2, varscan2
- KMT2A | c.2024C>T p.S675L | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as COSV100629033; called by muse, mutect2, varscan2
- KMT2A | c.2324C>T p.S775F | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.753); catalogued as COSV100629034; called by muse, mutect2, varscan2
- LRRC7 | c.4530C>A p.F1510L (on ENST00000651989 / NM_001370785.2; = p.F1430L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); catalogued as rs1558059721, COSV99227567; called by muse, mutect2, varscan2
- MAST1 | c.1707C>A p.D569E | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99263092; called by muse, mutect2, varscan2
- METTL22 | c.826+1G>T p.X276_splice | Splice Site (SNP) | VAF 17/39 reads (44%) | catalogued as COSV99371733; called by muse, mutect2, varscan2
- MINDY3 | c.598G>T p.E200* | Nonsense Mutation (SNP) | VAF 24/73 reads (33%) | catalogued as COSV53220053, COSV99510773; called by muse, mutect2, varscan2
- MROH5 | c.411C>G p.I137M | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.328); catalogued as COSV101436014, COSV101436128, COSV71301790; called by muse, mutect2, varscan2
- MS4A1 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV100619337, COSV99062615; called by muse, mutect2, varscan2
- NECTIN3 | c.1459T>A p.L487I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.514); catalogued as COSV100162498; called by muse, mutect2, varscan2
- NID1 | c.1016C>A p.T339N | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.14); catalogued as COSV99937651; called by muse, mutect2, varscan2
- NKD1 | c.1142C>T p.S381F | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.351); catalogued as COSV99194065; called by muse, mutect2, varscan2
- NTRK3 | c.441C>A p.F147L | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.261); catalogued as rs1417899959, COSV100446803; called by muse, mutect2, varscan2
- OPRK1 | c.1046A>G p.K349R | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV99654148; called by muse, mutect2, varscan2
- OR2A5 | c.208A>G p.I70V | Missense Mutation (SNP) | VAF 63/129 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV101278770; called by muse, mutect2, varscan2
- OR2M3 | c.461C>T p.T154M | Missense Mutation (SNP) | VAF 73/212 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs969274229, COSV101513446, COSV71759086; called by muse, mutect2, varscan2
- OR2T8 | c.788A>T p.H263L | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as COSV100178315, COSV60665132; called by muse, mutect2, varscan2
- PGA3 | c.162C>G p.F54L | Missense Mutation (SNP) | VAF 47/183 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV100337364; called by muse, mutect2, varscan2
- PIP | c.163G>T p.V55L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99344182; called by muse, mutect2, varscan2
- PKIB | c.14C>A p.S5* | Nonsense Mutation (SNP) | VAF 45/217 reads (21%) | catalogued as COSV99236454; called by muse, mutect2, varscan2
- PLPPR3 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs779341709, COSV100608796; called by muse, mutect2, varscan2
- PLS3 | c.703A>G p.I235V | Missense Mutation (SNP) | VAF 48/81 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV99171741; called by muse, mutect2, varscan2
- PLXNA2 | c.5680A>G p.S1894G | Missense Mutation (SNP) | VAF 54/97 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1307913781, COSV100885564; called by muse, mutect2, varscan2
- POLR3A | c.1642+1G>T p.X548_splice | Splice Site (SNP) | VAF 16/39 reads (41%) | catalogued as COSV100965682; called by muse, mutect2, varscan2
- POP1 | c.1747G>C p.G583R | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100855892, COSV100856033; called by muse, mutect2, varscan2
- PRAMEF20 | c.190C>A p.L64I | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs748835054, COSV100326341; called by muse, mutect2, varscan2
- PRPF4 | c.499C>T p.H167Y (on ENST00000374198 / NM_001322267.2; = p.H168Y on NM_004697.5) | Missense Mutation (SNP) | VAF 68/174 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100950706; called by muse, mutect2, varscan2
- PTPRN2 | c.218A>T p.E73V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV101234566; called by muse, mutect2, varscan2
- RBM23 | c.144G>T p.E48D | Missense Mutation (SNP) | VAF 127/621 reads (20%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV100321412; called by muse, mutect2, varscan2
- REM2 | c.334G>T p.D112Y | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV99944690; called by muse, mutect2, varscan2
- RHBDF1 | c.1993G>T p.G665W | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370237545, COSV99244770; called by muse, mutect2, varscan2
- RPS15A | c.142G>C p.G48R | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV100435915; called by muse, mutect2, varscan2
- RYR3 | c.921C>A p.D307E | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as COSV101212963; called by muse, mutect2, varscan2
- SACS | c.8594A>G p.H2865R | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.899); catalogued as COSV101207495; called by muse, mutect2, varscan2
- SATB2 | c.1196G>T p.R399L | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53480467, COSV99611466; called by muse, mutect2, varscan2
- SAXO2 | c.512A>T p.Y171F | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100255772; called by muse, mutect2, varscan2
- SEMA6D | c.440A>T p.Y147F | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as COSV100317132; called by muse, mutect2, varscan2
- SEPSECS | c.234A>T p.R78S | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV100258853; called by muse, mutect2, varscan2
- SERPINB9 | c.473G>T p.R158M | Missense Mutation (SNP) | VAF 48/87 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs1452537288, COSV101046619; called by muse, mutect2, varscan2
- SEZ6L | c.1550C>A p.A517D | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.632); catalogued as COSV99962262; called by muse, mutect2, varscan2
- SF1 | c.404G>T p.R135L | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV57114195, COSV57118742; called by muse, mutect2, varscan2
- SGCZ | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 24/110 reads (22%) | catalogued as COSV101170240; called by muse, mutect2, varscan2
- SLC25A11 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.005); catalogued as rs1276658607, COSV99337410; called by muse, mutect2, varscan2
- SLC8A2 | c.2422G>T p.D808Y | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1485461776, COSV99370035; called by muse, mutect2, varscan2
- SNTG1 | c.1433G>C p.C478S | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); catalogued as COSV52474750; called by muse, mutect2, varscan2
- SPATA31D1 | c.88A>G p.I30V | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.373); catalogued as COSV100782823; called by muse, mutect2, varscan2
- SPRED2 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100710256; called by muse, mutect2, varscan2
- SPTBN5 | c.4627G>T p.G1543C | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as COSV100311627; called by muse, mutect2, varscan2
- STARD13 | c.2131C>T p.R711C (on ENST00000336934 / NM_001243476.3; = p.R593C on NM_052851.3) | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755580938, COSV55227957; called by muse, mutect2, varscan2
- STK11 | c.509A>C p.Q170P | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as CM041080, COSV100480524, COSV58821587, COSV99045260; called by muse, mutect2, varscan2
- SWI5 | c.135C>A p.H45Q | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV100199677; called by muse, mutect2, varscan2
- TBX22 | c.899G>T p.W300L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100960830; called by muse, mutect2, varscan2
- TEX13A | c.140A>G p.E47G | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100781410; called by muse, mutect2, varscan2
- THBS2 | c.291G>C p.R97S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100827926; called by muse, mutect2, varscan2
- TRPM6 | c.5218G>C p.V1740L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as COSV100666499; called by muse, mutect2, varscan2
- TRPM7 | c.5103G>T p.R1701S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV100539943; called by muse, mutect2
- UQCC1 | c.667G>T p.D223Y | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100568626; called by muse, mutect2, varscan2
- USH1C | c.249-1G>T p.X83_splice | Splice Site (SNP) | VAF 17/33 reads (52%) | catalogued as COSV99140287; called by muse, mutect2, varscan2
- UTRN | c.876G>C p.E292D | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.218); catalogued as COSV100839980; called by muse, mutect2
- UTRN | c.877C>A p.H293N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as COSV100839981; called by muse, mutect2
- ZAP70 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs773287941, COSV99385641; called by muse, mutect2, varscan2
- ZNF117 | c.898A>T p.S300C | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs1266265453, COSV99275769; called by muse, mutect2, varscan2
- ZNF143 | c.1207A>T p.S403C | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100217886; called by muse, mutect2, varscan2
- ZNF215 | c.1402G>A p.G468R | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs200759402, COSV99549688; called by muse, mutect2, varscan2
- ZNF519 | c.977G>T p.G326V | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV101645549; called by muse, mutect2, varscan2
- ZNF521 | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100832457, COSV64122039; called by muse, mutect2, varscan2
- ZNF676 | c.1489A>G p.T497A (on ENST00000650058; = p.T465A on NM_001001411.3) | Missense Mutation (SNP) | VAF 61/106 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV101236229; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2728G>T p.E910* | Nonsense Mutation (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- BTNL9 | c.123del p.G42Afs*109 | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | called by mutect2, pindel, varscan2
- FRG2C | c.643del p.R215Gfs*53 | Frame Shift Del (DEL) | VAF 20/99 reads (20%) | called by mutect2, pindel, varscan2
- NKX2-2 | c.237_252del p.E81Pfs*98 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- PRAMEF15 | c.223_225delinsAA p.P75Nfs*69 | Frame Shift Del (DEL) | VAF 13/91 reads (14%) | called by pindel, varscan2*
- SORCS1 | c.284C>A p.T95N | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.003); called by mutect2, varscan2
- TRGV9 | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- ZNF862 | c.3099del p.I1034Sfs*13 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, pindel, varscan2
- AP1G1 | c.2310C>T p.V770= | Silent (SNP) | VAF 78/199 reads (39%) | catalogued as COSV100250563; called by muse, mutect2, varscan2
- BTNL8 | c.588C>T p.T196= | Silent (SNP) | VAF 45/78 reads (58%) | catalogued as rs1368425620, COSV51461276, COSV99180489; called by muse, mutect2, varscan2
- CA2 | c.582A>G p.P194= | Silent (SNP) | VAF 88/198 reads (44%) | catalogued as rs892997189, COSV99570115; called by muse, mutect2, varscan2
- COL11A1 | c.4461T>C p.D1487= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV100616966; called by muse, mutect2, varscan2
- COL20A1 | c.1530G>A p.E510= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV100490711, COSV58920365; called by muse, mutect2
- GAPDHS | c.987C>A p.A329= | Silent (SNP) | VAF 27/47 reads (57%) | catalogued as COSV99722370; called by muse, mutect2, varscan2
- HERC2 | c.8109T>C p.H2703= | Silent (SNP) | VAF 41/89 reads (46%) | catalogued as COSV99874432; called by muse, mutect2, varscan2
- HNF4A | c.816G>T p.L272= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV100291275, COSV100291462; called by muse, mutect2, varscan2
- IGHV3-72 | c.96G>A p.Q32= | Silent (SNP) | VAF 70/112 reads (63%) | catalogued as rs1192207985, COSV101455370, COSV70409705; called by muse, mutect2, varscan2
- ITIH2 | c.1128T>C p.Y376= | Silent (SNP) | VAF 36/69 reads (52%) | catalogued as COSV100623308; called by muse, mutect2, varscan2
- KCND3 | c.171G>T p.T57= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV100137597; called by muse, mutect2, varscan2
- KCTD16 | c.1122G>A p.R374= | Silent (SNP) | VAF 25/38 reads (66%) | catalogued as rs867136933, COSV101568823; called by muse, mutect2, varscan2
- LAMB4 | c.411G>T p.R137= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV99224351; called by muse, mutect2, varscan2
- LCK | c.135G>T p.R45= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV100287756; called by muse, mutect2, varscan2
- LINGO4 | c.1377G>C p.G459= | Silent (SNP) | VAF 41/107 reads (38%) | catalogued as COSV63216733, COSV63217151; called by muse, mutect2, varscan2
- MAP7D3 | c.2118A>G p.Q706= | Silent (SNP) | VAF 26/39 reads (67%) | catalogued as COSV100286402; called by muse, mutect2, varscan2
- MYO15A | c.10395G>A p.R3465= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as rs747753156, COSV52755130, COSV52762280; called by muse, mutect2, varscan2
- NEFL | c.1272C>T p.Y424= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as rs550984119, COSV99648009; called by muse, mutect2, varscan2
- OR2M7 | c.495C>A p.S165= | Silent (SNP) | VAF 78/210 reads (37%) | catalogued as rs377120211, COSV100522640; called by muse, mutect2, varscan2
- OR4A5 | c.585T>A p.T195= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV100157137; called by muse, mutect2, varscan2
- PAX4 | c.657C>T p.S219= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as rs762869940, COSV100490174; called by muse, mutect2, varscan2
- PHGDH | c.1341G>T p.G447= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV101025127; called by muse, mutect2, varscan2
- RGS2 | c.54G>A p.K18= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as COSV99343377; called by muse, mutect2, varscan2
- SERPINB9 | c.474G>A p.R158= | Silent (SNP) | VAF 47/86 reads (55%) | catalogued as COSV101046616; called by muse, mutect2, varscan2
- SLC2A14 | c.1374C>T p.I458= | Silent (SNP) | VAF 20/31 reads (65%) | catalogued as COSV61586932; called by muse, mutect2, varscan2
- SLC2A3 | c.1302C>T p.I434= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV99306695; called by muse, mutect2
- SLC8A2 | c.2421G>A p.Q807= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs1206578439, COSV99370037; called by muse, mutect2, varscan2
- SNRPA | c.474G>T p.P158= | Silent (SNP) | VAF 14/18 reads (78%) | catalogued as COSV99698874; called by muse, mutect2, varscan2
- STAB2 | c.840C>A p.P280= | Silent (SNP) | VAF 35/59 reads (59%) | catalogued as COSV101186044, COSV101186247; called by muse, mutect2, varscan2
- TG | c.7569G>T p.V2523= | Silent (SNP) | VAF 19/202 reads (9%) | catalogued as COSV99601376; called by muse, mutect2, varscan2
- PTPRK | c.578-1136A>T | Intron (SNP) | VAF 22/44 reads (50%) | called by muse, mutect2, varscan2
